Somatic mutation profile of tumor specimen 0DIR3Y from CCDI case PBBWBL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 7.4 years (2,685 days).
Specimen 0DIR3Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79976253-493c-4c4d-b7bc-0c6850036ca6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIQZQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3dd2d54-104a-477d-a142-0a46cefb5205

The open-access MAF lists 63 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 13, Intron 7, 3'UTR 4, Nonsense Mutation 2, 5'UTR 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1F | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 121/289 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1436373432; called by muse, varscan2
- CACNA1G | c.586+2T>A p.X196_splice | Splice Site (SNP) | VAF 135/400 reads (34%) | catalogued as COSV61725453; called by muse, varscan2
- CEACAM1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 124/355 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs943573065, COSV50725932; called by muse, varscan2
- COL7A1 | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 194/398 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470954674; called by muse, varscan2
- DNAH2 | c.6508G>A p.V2170M | Missense Mutation (SNP) | VAF 220/772 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779013637, COSV66717956; called by muse, varscan2
- FBXW7 | c.1265G>A p.G422D (on ENST00000281708 / NM_001349798.2; = p.G342D on NM_018315.5) | Missense Mutation (SNP) | VAF 234/378 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55902099; called by muse, varscan2
- FSTL4 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 188/409 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs151054673; called by muse, varscan2
- GPC5 | c.492C>G p.N164K | Missense Mutation (SNP) | VAF 178/420 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV65621630; called by muse, varscan2
- GUCY1A2 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 196/310 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV56506377; called by muse, varscan2
- HRH3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 93/310 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs752380770, CM117811, COSV58047957; called by muse, varscan2
- NBEA | c.5735G>A p.R1912H | Missense Mutation (SNP) | VAF 175/362 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs371714749; called by muse, varscan2
- NOTCH3 | c.4898C>T p.P1633L | Missense Mutation (SNP) | VAF 139/370 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.307); catalogued as rs375474414, COSV54644910; called by muse, varscan2
- NOTCH3 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.225); catalogued as rs200317373; called by muse, varscan2
- PCDHGA2 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 149/304 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.059); catalogued as rs778896419, COSV53964133; called by muse, varscan2
- SBF1 | c.4045C>T p.R1349* | Nonsense Mutation (SNP) | VAF 84/296 reads (28%) | catalogued as rs752869887; called by muse, varscan2
- STX2 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 108/494 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs1263306620; called by muse, varscan2
- SYCE1L | c.518G>C p.R173P | Missense Mutation (SNP) | VAF 138/348 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as rs936503255; called by muse, varscan2
- TATDN1 | c.266C>G p.P89R | Missense Mutation (SNP) | VAF 132/437 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs770518945; called by muse, varscan2
- TGM5 | c.1108G>A p.V370I (on ENST00000220420 / NM_201631.4; = p.V288I on NM_004245.4) | Missense Mutation (SNP) | VAF 142/396 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs200175407, COSV55010657; called by muse, varscan2
- TMEM104 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 112/432 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753954018, COSV59107697; called by muse, varscan2
- ATP1B2 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 222/751 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, varscan2
- CNGA2 | c.38C>G p.A13G | Missense Mutation (SNP) | VAF 218/494 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.073); called by muse, varscan2
- DUOX2 | c.4099T>C p.F1367L | Missense Mutation (SNP) | VAF 180/624 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, varscan2
- FBXW7 | c.1523A>C p.Q508P (on ENST00000281708 / NM_001349798.2; = p.Q428P on NM_018315.5) | Missense Mutation (SNP) | VAF 156/533 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, varscan2
- GDPD5 | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 180/583 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.101); called by muse, varscan2
- LRRC1 | c.1166A>C p.D389A | Missense Mutation (SNP) | VAF 54/340 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, varscan2
- LRRC9 | c.1314C>A p.N438K | Missense Mutation (SNP) | VAF 396/550 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); called by muse, varscan2
- MUC12 | c.11231A>T p.E3744V (on ENST00000379442; = p.E3601V on NM_001164462.1) | Missense Mutation (SNP) | VAF 74/895 reads (8%) | SIFT deleterious (0); called by muse, varscan2
- ODAM | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 142/324 reads (44%) | called by muse, varscan2
- OR2A25 | c.446T>C p.I149T | Missense Mutation (SNP) | VAF 168/550 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, varscan2
- PPP2CA | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.141); called by muse, varscan2
- RFX1 | c.1499G>A p.G500D | Missense Mutation (SNP) | VAF 102/232 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RFX4 | c.1953del p.T652Lfs*8 (on ENST00000392842 / NM_213594.3; = p.T558Lfs*8 on NM_032491.6) | Frame Shift Del (DEL) | VAF 98/452 reads (22%) | called by pindel, varscan2
- SLFN13 | c.2143C>G p.L715V | Missense Mutation (SNP) | VAF 182/402 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- TAS2R9 | c.638G>C p.R213P | Missense Mutation (SNP) | VAF 116/710 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.22); called by muse, varscan2
- TRIT1 | c.923A>G p.K308R | Missense Mutation (SNP) | VAF 136/577 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.062); called by muse, varscan2
- UBE2E3 | c.584A>T p.D195V | Missense Mutation (SNP) | VAF 224/354 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- ALK | c.2622C>T p.S874= | Silent (SNP) | VAF 180/589 reads (31%) | catalogued as rs528315610, COSV66561513; ClinVar: likely benign; called by muse, varscan2
- BTBD7 | c.1194A>T p.S398= | Silent (SNP) | VAF 186/493 reads (38%) | called by muse, varscan2
- CTRC | c.549C>T p.H183= | Silent (SNP) | VAF 230/496 reads (46%) | catalogued as rs554399153, COSV65622007; ClinVar: likely benign; called by muse, varscan2
- DLG4 | c.1200C>T p.F400= (on ENST00000399506 / NM_001321075.3; = p.F443= on NM_001365.4) | Silent (SNP) | VAF 84/306 reads (27%) | catalogued as rs759927233, COSV57240139; called by muse, varscan2
- EPHX4 | c.534T>A p.I178= | Silent (SNP) | VAF 134/624 reads (21%) | called by muse, varscan2
- GCNA | c.963T>C p.D321= | Silent (SNP) | VAF 300/783 reads (38%) | called by muse, varscan2
- GZMM | c.621G>T p.S207= | Silent (SNP) | VAF 124/412 reads (30%) | called by muse, varscan2
- IFT57 | c.243C>G p.G81= | Silent (SNP) | VAF 167/369 reads (45%) | catalogued as COSV52712661; called by muse, varscan2
- NBAS | c.6438C>T p.D2146= | Silent (SNP) | VAF 141/242 reads (58%) | called by muse, varscan2
- NBEAL2 | c.3912G>A p.P1304= | Silent (SNP) | VAF 136/322 reads (42%) | catalogued as rs1377726129; called by muse, varscan2
- POU5F1 | c.97C>A p.R33= | Silent (SNP) | VAF 162/393 reads (41%) | called by muse, varscan2
- RFPL2 | c.681C>T p.S227= | Silent (SNP) | VAF 189/718 reads (26%) | catalogued as rs765598608; called by muse, varscan2
- SLC12A1 | c.873T>C p.D291= | Silent (SNP) | VAF 62/244 reads (25%) | called by muse, varscan2
- CXCL5 | c.110-48C>T | Intron (SNP) | VAF 109/212 reads (51%) | called by muse, varscan2
- DPP6 | c.-81G>T | 5'UTR (SNP) | VAF 18/60 reads (30%) | called by muse, varscan2
- ECSIT | c.*33C>G | 3'UTR (SNP) | VAF 96/254 reads (38%) | catalogued as rs1277446806; called by muse, varscan2
- HSD17B12 | c.-14C>G | 5'UTR (SNP) | VAF 77/281 reads (27%) | called by muse, varscan2
- LTBP3 | c.662-19C>A | Intron (SNP) | VAF 82/302 reads (27%) | called by muse, varscan2
- PPP4R3C | c.*13G>A | 3'UTR (SNP) | VAF 74/174 reads (43%) | called by muse, varscan2
- PREX2 | c.2716-2782C>G | Intron (SNP) | VAF 134/468 reads (29%) | catalogued as COSV55754826; called by muse, varscan2
- RIDA | c.172-26T>G | Intron (SNP) | VAF 131/358 reads (37%) | called by muse, varscan2
- SCML1 | c.*64G>A | 3'UTR (SNP) | VAF 100/190 reads (53%) | called by muse, varscan2
- SLITRK1 | c.*5C>G | 3'UTR (SNP) | VAF 89/174 reads (51%) | catalogued as COSV100999792; called by muse, varscan2
- TRPM1 | c.-63-4446_-63-4444del | Intron (DEL) | VAF 66/214 reads (31%) | catalogued as rs1375820246; called by pindel, varscan2
- TSHZ2 | c.41-67823G>A | Intron (SNP) | VAF 90/316 reads (28%) | catalogued as rs1376138277; called by muse, varscan2
- USP33 | c.1483-61A>G | Intron (SNP) | VAF 16/124 reads (13%) | called by muse, varscan2
